FM case AD14861 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/0b75ea0e-3203-4b83-96e6-61cfcb1cf908

Male, 61.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the small intestine; metastasis. Tumor nuclei on the sequenced sample's slide: 25% (pathologist estimate recorded by GDC). Sample type: Metastatic.
